Surgical pathology report (de-identified scan), TCGA case TCGA-HI-7168, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-HI-7168-01A (Primary Tumor).

[page 1 of 2]
Sex: M

Source of Specimen(s):

- 1: Lymph Node, right pelvic
- 2: Lymph Node, left pelvic
- 3: Peri prostatic fat
- 4: Prostate and Seminal Vessicles
- 5: Margin, bladder neck

Gross Description:

Received in five parts.

Source of Tissue: 1. Labeled # 1, "right pelvic lymph node"

Gross Description: Received fresh in a container labeled , right pelvic lymph node". It consists of a few tan to yellow rubbery lymph nodes measuring from 0.4 up to 2.5 cm. One single large bisected lymph node is submitted in 1A and the rest of the tissue in 1B and 1C. Entirely submitted in 1A-C.

Source of Tissue: 2. Labeled # 2, "left pelvic lymph node"

Gross Description: Received fresh in a container labeled , left pelvic lymph node". It consists of a few soft to firm, predominantly fatty appearing lymph nodes ranging from 0.6 up to 3.8 cm. Most of the lymph nodes are predominantly fatty. The larger node is sectioned disclosing a fatty cut surface. 2A contains a single sectioned lymph node, 2B and 2C contains multiple single lymph nodes. Entirely submitted in 2A-C.

Source of Tissue: 3. Labeled #3, "periprostatic fat"

Gross Description: Received fresh in a container labeled , periprostatic fat". It consists of two fragments of lobulated fatty tissue measuring 1.6 x 1.5 x 0.7 cm. No suspicious lesions or masses are identified. Entirely submitted in 3A.

Source of Tissue: 4. Labeled # 4, "prostate and seminal vesicles"

Gross Description: Received fresh in a container labeled , prostate and seminal vesicles". It consists of a 46 gram prostate gland measuring 4.3 x 4.1 x 4.2 cm. The right side is inked black and left side blue and a probe inserts easily through the prostatic urethra. Sections disclose a glandular yellowish-tan homogeneous cut surface with an appreciable amount of prostatic concretions noted. In the left superior-posterior aspect there is a white firm zone of prostate measuring 2.5 x 2.5 x 2.0 cm. This area is grossly consistent with tumor and extends into the left seminal vesicle approximately 7.0 cm. The tumor comes very close to the left and midline base [4D]. The bilateral seminal vesicles measure 2.0 x 1.5 x 1.0 cm and, as aforementioned possible

[page 2 of 2]
lesional tissue is closest to the left side. Representative sections are submitted in 4A-N.

Designation of Sections: 4A-4B- apex, 4C-4D- base, 4E-4H- right side of prostate gland [E- anterior, F- mid, G-H- superior-posterior], 4I-4L- left side of prostate gland [I- anterior, J- mid, K-L- superior-posterior], 4M- right vas deferens and seminal vesicle, 4N- left vas deferens and seminal vesicle

Source of Tissue: 5. Labeled # 5, "bladder neck margin"

Gross Description: Received fresh in a container labeled, , bladder neck margin". It consists of a fragment of fat measuring 0.7 x 0.6 x 0.6 cm. Submitted in toto in 5A.

Final Diagnosis:

1. Right pelvic lymph nodes, biopsy:

- Three lymph nodes, No tumor seen (0/3).

2. Left pelvic lymph nodes, biopsy:

- Six lymph nodes, No tumor seen (0/6).

3. Periprostatic fat, biopsy:

- No tumor seen.

4. Prostate and seminal vesicles, radical prostatectomy:

- Prostatic adenocarcinoma, Gleason's score 4+5=9. Tumor is multifocal in both sides of the gland and represents about 20% of sampled tissue.

Extracapsular soft tissue extension is seen on the left side. Tumor invades into left seminal vesicle.

- Inked surgical margins are free of tumor.

5. Bladder neck margin, excision:

- No tumor seen.

Source: NCI Genomic Data Commons file 44d33cdc-7161-4187-85c5-81bf04be34b8 (TCGA-HI-7168.D29AF7D7-996D-44A9-A571-878EA0F95403.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).